Somatic mutation profile of tumor specimen ALCH-B4SJ-TTP1-A (aliquot ALCH-B4SJ-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4SJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.8 years (27,331 days).
Specimen ALCH-B4SJ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eff36b86-18c8-4bf3-86b5-3a54025cebd8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4SJ-NB1-A (Blood Derived Normal), aliquot ALCH-B4SJ-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0089485-9bc6-44c8-bb37-2374e4911a16

The open-access MAF lists 56 somatic variants for this specimen: 38 protein-altering or splice-affecting, 13 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 13, Nonsense Mutation 4, Intron 2, Frame Shift Del 1, Splice Site 1, 5'Flank 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 1288/2058 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 87/442 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs863224683, CM016206, COSV52686543, COSV52692226, COSV99368721; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BYSL | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 24/400 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs750647786; called by muse, mutect2
- CAPN15 | c.1709G>T p.R570L | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as rs548702059; called by muse, mutect2, varscan2
- DGKB | c.374C>A p.A125E | Missense Mutation (SNP) | VAF 26/562 reads (5%) | SIFT tolerated (0.87); PolyPhen benign (0.024); catalogued as rs1378719804, COSV51821159; called by muse, mutect2
- DRC3 | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 34/261 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs760498955; called by muse, mutect2, varscan2
- GLG1 | c.1369C>T p.R457* | Nonsense Mutation (SNP) | VAF 57/475 reads (12%) | catalogued as COSV52664415; called by muse, mutect2, varscan2
- GPRASP1 | c.1483C>G p.Q495E | Missense Mutation (SNP) | VAF 33/314 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64355184; called by muse, mutect2, varscan2
- HELQ | c.2383C>T p.L795F | Missense Mutation (SNP) | VAF 34/480 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV55028285, COSV99787331; called by muse, mutect2
- KCNK4 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777868070, COSV100107662, COSV60454723; called by muse, mutect2
- LRP5 | c.4301C>T p.P1434L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV99591726; called by muse, mutect2, varscan2
- MRAP2 | c.44C>A p.S15* | Nonsense Mutation (SNP) | VAF 40/274 reads (15%) | catalogued as COSV57634132, COSV57634287; called by muse, mutect2, varscan2
- OR2T2 | c.189G>T p.L63F | Missense Mutation (SNP) | VAF 177/2012 reads (9%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.998); catalogued as rs755379689; called by muse, mutect2
- TRAF7 | c.2010C>A p.C670* | Nonsense Mutation (SNP) | VAF 43/391 reads (11%) | catalogued as rs1283228225, COSV100398997, COSV58217446; called by muse, mutect2, varscan2
- WIPF3 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.5); catalogued as rs1171511127; called by muse, mutect2, varscan2
- AHNAK2 | c.14927A>G p.D4976G | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- ASTN1 | c.1548G>C p.Q516H | Missense Mutation (SNP) | VAF 31/580 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.568); called by muse, mutect2
- ATRAID | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CDK14 | c.37A>T p.I13F | Missense Mutation (SNP) | VAF 34/373 reads (9%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.11); called by muse, mutect2
- CERKL | c.1211+1G>A p.X404_splice (on ENST00000339098 / NM_001030311.2; = p.X378_splice on NM_201548.5) | Splice Site (SNP) | VAF 14/385 reads (4%) | called by muse, mutect2
- CPT1A | c.606G>A p.M202I | Missense Mutation (SNP) | VAF 62/744 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); called by muse, mutect2
- F5 | c.2584C>T p.H862Y | Missense Mutation (SNP) | VAF 32/259 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GABRA5 | c.1340C>T p.T447M | Missense Mutation (SNP) | VAF 32/316 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- GAREM2 | c.2400G>A p.W800* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | called by muse, varscan2
- GUCY2D | c.2653G>T p.D885Y | Missense Mutation (SNP) | VAF 111/516 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LARP7 | c.1121T>C p.I374T | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- LYN | c.1354G>A p.V452M | Missense Mutation (SNP) | VAF 29/316 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MKI67 | c.1353A>T p.Q451H | Missense Mutation (SNP) | VAF 50/262 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MYO15B | c.3309A>C p.Q1103H | Missense Mutation (SNP) | VAF 81/308 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- N4BP1 | c.2575G>A p.E859K | Missense Mutation (SNP) | VAF 65/440 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- N4BP1 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 84/746 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCAM1 | c.1582C>A p.Q528K (on ENST00000316851 / NM_181351.5; = p.Q518K on NM_000615.7) | Missense Mutation (SNP) | VAF 34/340 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2
- PHKB | c.1144C>G p.P382A | Missense Mutation (SNP) | VAF 90/527 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, varscan2
- PLEC | c.111C>G p.H37Q | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TOPORS | c.2470C>G p.H824D | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT tolerated (0.81); PolyPhen benign (0.031); called by muse, mutect2
- TRIM46 | c.294G>C p.K98N | Missense Mutation (SNP) | VAF 19/360 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); called by muse, mutect2
- USH2A | c.11355del p.P3786Lfs*6 | Frame Shift Del (DEL) | VAF 140/1014 reads (14%) | called by pindel, varscan2
- ZDHHC15 | c.209G>T p.W70L | Missense Mutation (SNP) | VAF 40/589 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- ABCC8 | c.702C>T p.N234= | Silent (SNP) | VAF 63/512 reads (12%) | catalogued as rs758289249; called by muse, mutect2, varscan2
- ANKK1 | c.60C>T p.D20= | Silent (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- APOB | c.3876C>T p.N1292= | Silent (SNP) | VAF 66/588 reads (11%) | called by muse, mutect2, varscan2
- IFT52 | c.549T>A p.V183= | Silent (SNP) | VAF 87/838 reads (10%) | called by muse, mutect2, varscan2
- NCAPD2 | c.1359G>A p.E453= | Silent (SNP) | VAF 95/765 reads (12%) | catalogued as rs200847598; called by muse, mutect2, varscan2
- POLRMT | c.636G>T p.G212= | Silent (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2
- RANGAP1 | c.411G>A p.K137= | Silent (SNP) | VAF 12/230 reads (5%) | called by muse, mutect2
- SH2D1A | c.114A>T p.P38= | Silent (SNP) | VAF 60/766 reads (8%) | called by muse, mutect2
- SLC9A3 | c.1245C>T p.R415= | Silent (SNP) | VAF 93/419 reads (22%) | catalogued as rs143761751, COSV99375879; called by muse, mutect2, varscan2
- SPEN | c.9021C>A p.I3007= | Silent (SNP) | VAF 15/204 reads (7%) | catalogued as COSV101004925; called by muse, mutect2
- THBS2 | c.18C>T p.V6= | Silent (SNP) | VAF 61/398 reads (15%) | called by muse, mutect2, varscan2
- TRGV4 | c.144C>A p.T48= | Silent (SNP) | VAF 188/994 reads (19%) | called by muse, mutect2
- UNC13B | c.12C>G p.L4= | Silent (SNP) | VAF 13/118 reads (11%) | called by muse, mutect2, varscan2
- BAP1 | c.1891-56G>A | Intron (SNP) | VAF 42/414 reads (10%) | catalogued as rs767198116; called by muse, mutect2, varscan2
- GFM1 | c.81+17_81+18del | Intron (DEL) | VAF 54/226 reads (24%) | called by pindel, varscan2
- MIR331 | n.26C>T | RNA (SNP) | VAF 130/612 reads (21%) | called by muse, mutect2, varscan2
- PHACTR3 | c.*15G>A | 3'UTR (SNP) | VAF 10/72 reads (14%) | catalogued as COSV63033827; called by muse, mutect2, varscan2
- PSMD5 | chr9:120843131 A>G | 5'Flank (SNP) | VAF 21/134 reads (16%) | catalogued as rs548237507; called by muse, mutect2, varscan2
